CCDI case PBCPDR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/a68dd800-b1ef-4817-a198-416c38a13bf7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Giant cell tumor of soft parts, NOS: ICD-O-3 morphology code: 9251/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 4.2 years (1,552 days).

Biospecimens (3 samples)
- Sample 0DXXW3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXXX8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DXXY3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
